Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A262, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A262-06A (Metastatic).

1CD-0-3

Melanoma, malignant, NOS 8720/3

Site: skin, breast c 44.5 h 4/27/11

SPECIMENS:

- A. LEFT AXILLARY LYMPH NODE
- B. WIDE EXCISION LEFT BREAST INTRANSIT MELANOMA

SPECIMEN(S):

- A. LEFT AXILLARY LYMPH NODE
- B. WIDE EXCISION LEFT BREAST INTRANSIT MELANOMA

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

TPA: left axillary lymph node: negative for melanoma. Called to Dr. by Dr. at

GROSS DESCRIPTION:

A. LEFT AXILLARY LYMPH NODE

Received fresh and labeled "left axillary lymph nodes", consists of one nodular tissue measuring 1.6 x 1.0 x 0.7 cm. The specimen is serially sectioned and touch preparation is performed. The entire specimen is submitted in cassette A1 to A2.

B. WIDE EXCISION LEFT BREAST IN-TRANSIT MELANOMA

Received fresh and labeled as "wide excision left breast in-transit melanoma", consists of one skin ellipse with attached adipose tissue. The skin ellipse measures 6.0 x 2.0 cm with 0.37 in thickness. The attached adipose tissue measures 7.2 x 3.0 x 2.2 cm. One stitch is attached to the specimen designated as lateral. The specimen is inked as follows: superior-blue, inferior-orange, medial-green, lateral-red, and posterior-black. The specimen is serially sectioned starting from posterior and reveals one white tan tumor nodule measuring 0.5-cm in greatest dimension. The tumor is 1.0-cm to the superior, inferior, and posterior margins, 4-cm to the lateral margin, and 3.0-cm to the medial margin. Tumor tissue is procured. Representative sections are submitted as follows:

- B1: Medial margin (including skin ellipse tip)
- B2: Lateral margin (including skin ellipse tip)
- B3-B4: Full thickness section of tumor, bisected
- B5: Superior-lateral skin and soft tissue margin, en face
- B6: Inferior-lateral skin and soft tissue margin, en face
- B7: Superior-medial skin and soft tissue margin, en face
- B8: Inferior-medial skin and soft tissue margin, en face
- B9: Additional posterior margin (lateral), en face
- B10: Additional posterior margin (medial), en face

DIAGNOSIS:

- A. LYMPH NODE, LEFT AXILLARY, BIOPSY:
- ONE LYMPH NODE NEGATIVE FOR MELANOMA (0/1)
- B. SKIN AND SOFT TISSUE OF LEFT BREAST, WIDE EXCISION:
- MALIGNANT MELANOMA WITHIN SUBCUTIS (0.8 CM), CONSISTENT WITH IN-TRANSIT METASTASIS
- MARGINS ARE NEGATIVE FOR MELANOMA
- BENIGN MAMMARY PARENCHYMA

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left breast melanoma

Gross Dictation: Pathologist,
Microscopic/Diagnostic Dictation: Pathologist,
Final Review: Pathologist,
Final: Pathologist,

Source: NCI Genomic Data Commons file 125abda7-113d-4825-9736-a489a10438f3 (TCGA-GN-A262.7F620D7C-8D45-4E7F-9A6B-C702EB26EBF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).